Somatic mutation profile of tumor specimen 0DF0B9 from CCDI case PBBPCE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.6 years (4,249 days).
Specimen 0DF0B9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e883e47f-5012-48b9-89bc-6bd8b092bf82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF0BH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60bd4d63-a1d7-4b83-ae07-859be32e2cb8

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NKX2-3 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 150/422 reads (36%) | catalogued as rs1355527905; called by muse, mutect2, varscan2
- SP100 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 120/350 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.586); catalogued as rs142094556; called by muse, mutect2, varscan2
- FAT2 | c.8909A>G p.K2970R | Missense Mutation (SNP) | VAF 243/701 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- SOX10 | c.887_921del p.E296Gfs*94 | Frame Shift Del (DEL) | VAF 134/406 reads (33%) | called by mutect2, varscan2
- TOGARAM1 | c.4758A>G p.P1586= | Silent (SNP) | VAF 257/751 reads (34%) | called by muse, mutect2, varscan2
